Somatic mutation profile of tumor specimen TCGA-56-A5DS-01A (aliquot TCGA-56-A5DS-01A-11D-A27K-08) from TCGA case TCGA-56-A5DS, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.2 years (26,355 days).
Specimen TCGA-56-A5DS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28193159-c2af-49b4-875b-7adf25fda5da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A5DS-10A (Blood Derived Normal), aliquot TCGA-56-A5DS-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e6c0993-325a-40f7-a9ab-dfd41f671f04

The open-access MAF lists 225 somatic variants for this specimen: 170 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 51, Nonsense Mutation 10, Frame Shift Del 3, RNA 3, Splice Region 2, Nonstop Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1559G>T p.C520F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821918; called by muse, mutect2, varscan2
- ADAMTS17 | c.2887G>T p.A963S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.13); catalogued as COSV99170392; called by muse, mutect2, varscan2
- ADGRB3 | c.2135C>G p.A712G | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as rs1360705070, COSV100999969; called by muse, mutect2, varscan2
- ADSL | c.1138A>T p.M380L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV99341983; called by mutect2, varscan2
- ALG13 | c.3391C>T p.H1131Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99321726; called by muse, mutect2, varscan2
- AMELX | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as COSV100497274; called by muse, mutect2, varscan2
- AP002512.3 | c.722G>T p.R241M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99687791; called by muse, mutect2, varscan2
- ARHGAP4 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1569546003, COSV100604122, COSV63130805; called by muse, mutect2, varscan2
- ARID1B | c.6008G>A p.C2003Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99267359; called by muse, mutect2, varscan2
- ATAD3A | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100186094; called by muse, mutect2, varscan2
- ATP4A | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99382177; called by muse, mutect2, varscan2
- ATP8B4 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs762729078, COSV52719814; called by muse, mutect2, varscan2
- AXIN1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV51994091, COSV99249368; called by muse, mutect2, varscan2
- BEND2 | c.542G>C p.W181S | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV101191823; called by muse, mutect2, varscan2
- BRWD3 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100955693; called by muse, mutect2, varscan2
- BSPRY | c.765C>G p.S255R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.424); catalogued as COSV99444801; called by muse, mutect2, varscan2
- CA10 | c.713C>A p.S238* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99561823; called by muse, mutect2, varscan2
- CCDC141 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV55368151; called by muse, mutect2, varscan2
- CCDC42 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV99549691; called by muse, mutect2, varscan2
- CD163L1 | c.1986C>G p.C662W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549745; called by muse, mutect2, varscan2
- CD163L1 | c.863A>C p.H288P | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV100549746; called by muse, mutect2, varscan2
- CDH10 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs543550761, COSV100051806, COSV52594816; called by muse, mutect2
- CDK12 | c.85A>T p.S29C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101420373; called by muse, mutect2
- CDK18 | c.394G>A p.D132N (on ENST00000506784 / NM_212503.3; = p.D102N on NM_002596.4) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV63727263; called by muse, mutect2, varscan2
- CEMP1 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.567); catalogued as rs779553383, COSV99565640; called by muse, mutect2, varscan2
- CLCN5 | c.1882T>G p.S628A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV100259837; called by muse, mutect2
- CMTM7 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV100569843; called by muse, mutect2
- COL22A1 | c.4741C>A p.P1581T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100276585, COSV57346681; called by muse, mutect2, varscan2
- COL6A3 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs113538665, COSV55107615; called by muse, mutect2
- CSMD3 | c.8117G>A p.R2706K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV99826248, COSV99831984; called by muse, mutect2, varscan2
- CTNND2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs61750706; called by muse, mutect2, varscan2
- CXorf56 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57438137; called by muse, mutect2, varscan2
- DISP1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV99450110; called by muse, mutect2, varscan2
- DNAI3 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99641437; called by muse, mutect2, varscan2
- DNAJC14 | c.1753A>G p.T585A | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV99670653; called by muse, mutect2, varscan2
- DSC2 | c.2212A>T p.I738F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99199503; called by muse, mutect2, varscan2
- DUSP7 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99623414; called by muse, mutect2, varscan2
- EGR4 | c.1132G>T p.D378Y (on ENST00000545030; = p.D275Y on NM_001965.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV101474209; called by muse, mutect2
- FAM153B | c.882G>T p.E294D (on ENST00000253490; = p.E217D on NM_001265615.1) | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV99499095; called by muse, mutect2, varscan2
- FAT1 | c.1520_1521del p.H507Rfs*6 | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | catalogued as rs775634180; called by mutect2, pindel, varscan2
- FAT3 | c.8353G>C p.A2785P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99962547; called by muse, mutect2, varscan2
- FBXO42 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100981659; called by muse, mutect2
- FGD1 | c.2240C>G p.T747S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100910834; called by muse, mutect2, varscan2
- FGD1 | c.1513G>T p.G505C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100910836; called by muse, mutect2
- FGD1 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.351); catalogued as COSV100910837; called by muse, mutect2, varscan2
- FGD6 | c.1613G>C p.R538T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.15); catalogued as COSV100676396; called by muse, mutect2, varscan2
- FGD6 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); catalogued as COSV100676397; called by muse, mutect2, varscan2
- FMN2 | c.3851A>G p.K1284R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578174204, COSV100143154; called by muse, mutect2, varscan2
- FMR1 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.253); catalogued as rs781918121, COSV99502992; called by muse, mutect2, varscan2
- GAL3ST3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757211741, COSV100360733; called by muse, mutect2
- GALNT2 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64196764; called by muse, mutect2, varscan2
- GCAT | c.1187A>T p.H396L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99959661; called by muse, mutect2, varscan2
- GLA | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99516191, COSV99516347; called by muse, mutect2, varscan2
- GLA | c.547+2T>C p.X183_splice | Splice Site (SNP) | VAF 11/120 reads (9%) | catalogued as COSV99516193; called by muse, mutect2, varscan2
- GNLY | c.51A>G p.P17= | Splice Region (SNP) | VAF 5/66 reads (8%) | catalogued as COSV99808865; called by muse, mutect2
- GPR61 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as COSV100879826; called by muse, mutect2, varscan2
- HERC1 | c.10178G>A p.R3393H | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs200318759, COSV71246577; called by muse, mutect2
- IGHV1-3 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs368720034; called by muse, mutect2, varscan2
- IGKV3-11 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758826142; called by muse, mutect2, varscan2
- IGSF3 | c.2119A>G p.T707A (on ENST00000369486 / NM_001007237.3; = p.T727A on NM_001542.4) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100604165; called by muse, mutect2, varscan2
- IL9R | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV99729327; called by muse, mutect2, varscan2
- ILDR2 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV54836336, COSV99613296; called by muse, mutect2, varscan2
- IPO5 | c.2320G>C p.A774P | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99847032; called by muse, mutect2
- KBTBD6 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV101068716; called by muse, mutect2, varscan2
- KCND1 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54413714, COSV54415974; called by muse, mutect2, varscan2
- KCNH6 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59001926; called by muse, mutect2
- KDM1A | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1217824799, COSV100752360, COSV63090455; called by muse, mutect2, varscan2
- KIF21A | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100735325; called by muse, mutect2
- KIF2B | c.1410G>C p.E470D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV99274774; called by muse, mutect2, varscan2
- KIF4A | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV100979403; called by muse, mutect2, varscan2
- KIR2DL1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779537643, COSV52406976; called by muse, mutect2, varscan2
- KNDC1 | c.4565G>T p.S1522I | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100463510; called by muse, mutect2
- KRT76 | c.1876T>G p.S626A | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); catalogued as COSV100195925; called by muse, mutect2, varscan2
- LAMA1 | c.7540T>G p.F2514V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055207; called by muse, mutect2, varscan2
- LAMA1 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101055208; called by muse, mutect2, varscan2
- LRRC17 | c.288G>T p.L96F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50866604, COSV99978246; called by muse, mutect2, varscan2
- LSAMP | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100369357; called by muse, mutect2
- MAP3K10 | c.469A>T p.I157L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99454033; called by muse, mutect2, varscan2
- MAP3K15 | c.2146G>C p.V716L | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100134195; called by muse, mutect2, varscan2
- MED21 | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99282009; called by muse, mutect2, varscan2
- MGAM | c.5368G>T p.G1790C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV101527387; called by muse, mutect2, varscan2
- MYH1 | c.5341G>C p.A1781P | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV56849501, COSV99875018; called by muse, mutect2, varscan2
- MYO16 | c.3658G>A p.A1220T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs137956492; called by muse, mutect2, varscan2
- NAV3 | c.604C>G p.R202G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57080262, COSV57106346, COSV99887406; called by muse, mutect2, varscan2
- NEB | c.7853T>G p.L2618* | Nonsense Mutation (SNP) | VAF 45/474 reads (9%) | catalogued as COSV99415719; called by muse, mutect2
- NGRN | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58960797; called by muse, mutect2, varscan2
- NUP133 | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99772623; called by muse, mutect2, varscan2
- NUP88 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.42); catalogued as COSV99851525; called by muse, mutect2, varscan2
- OR10A6 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV100564239; called by muse, mutect2, varscan2
- OR10K1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV99193255; called by muse, mutect2, varscan2
- OR10W1 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101223614; called by muse, mutect2
- OR11G2 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100639897, COSV100639919; called by muse, mutect2, varscan2
- OR1S1 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100515255; called by muse, mutect2
- OR2A25 | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV101376343; called by muse, mutect2, varscan2
- PCSK7 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs751156091, COSV100309220; called by muse, mutect2
- PIKFYVE | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100009944; called by muse, mutect2, varscan2
- PKHD1 | c.6460G>T p.V2154F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100581370; called by muse, mutect2
- PKHD1 | c.5591T>C p.L1864P | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100581372; called by muse, mutect2, varscan2
- PLCD1 | c.619A>T p.M207L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99378486; called by muse, mutect2, varscan2
- PLCH1 | c.4286C>G p.T1429S (on ENST00000340059 / NM_001130960.2; = p.T1421S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.01); catalogued as COSV100395736; called by muse, mutect2
- PLXNA3 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859822, COSV100860202; called by muse, mutect2, varscan2
- PNMA3 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV100937555; called by muse, mutect2, varscan2
- POU2F1 | c.953G>A p.G318E (on ENST00000541643 / NM_001365848.1; = p.G341E on NM_002697.4) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54825477; called by muse, mutect2
- PPFIA2 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100331843, COSV61055575; called by muse, mutect2, varscan2
- PPP1R10 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs764446270, COSV100919755; called by muse, mutect2, varscan2
- PREX2 | c.3903G>T p.W1301C | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99905370; called by muse, mutect2
- PRKCQ | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99576390; called by muse, mutect2, varscan2
- PRPF4 | c.1333C>T p.P445S (on ENST00000374198 / NM_001322267.2; = p.P446S on NM_004697.5) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100950631; called by muse, mutect2, varscan2
- PTPRC | c.2665A>G p.R889G | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722170; called by muse, mutect2, varscan2
- RAB38 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54713148; called by muse, mutect2
- RCOR3 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100879479; called by muse, mutect2, varscan2
- REG1A | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.564); catalogued as COSV99286671; called by muse, mutect2
- REG1A | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV99286672; called by muse, mutect2
- RELCH | c.2398A>G p.I800V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs761215171, COSV99901499; called by muse, mutect2, varscan2
- RGS7 | c.368C>A p.P123Q | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100465015, COSV58541366; called by muse, mutect2, varscan2
- RGS9 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99287173; called by muse, mutect2, varscan2
- RNF17 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV55040820, COSV55043400; called by muse, mutect2, varscan2
- RUVBL1 | c.1279A>T p.K427* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100494064; called by muse, mutect2, varscan2
- RXFP3 | c.1047C>A p.S349R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV100347339; called by mutect2, varscan2
- SCFD1 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100356101; called by muse, mutect2, varscan2
- SEC24C | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100226557, COSV59539860; called by muse, mutect2, varscan2
- SERPINB1 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1181171739, COSV101058361; called by muse, mutect2, varscan2
- SH3KBP1 | c.1991C>A p.S664* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101115679, COSV101116442; called by muse, mutect2, varscan2
- SIGLEC12 | c.863C>A p.P288H (on ENST00000291707 / NM_053003.4; = p.P170H on NM_033329.2) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99389109; called by muse, mutect2, varscan2
- SLC17A6 | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as COSV54138555, COSV99580854; called by muse, mutect2, varscan2
- SLC17A8 | c.1764A>G p.I588M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100035236; called by muse, mutect2, varscan2
- SLC25A24 | c.1174G>C p.G392R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51449825; called by muse, mutect2, varscan2
- SLC30A5 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV101173552; called by muse, mutect2, varscan2
- SLC35C1 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100029338; called by muse, mutect2, varscan2
- SLC39A12 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV101069861; called by muse, mutect2, varscan2
- SLC6A14 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as COSV100903076; called by muse, mutect2
- SLFN13 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV53192061, COSV99539763; called by muse, mutect2
- SLFN13 | c.2355G>T p.L785F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99539765; called by muse, mutect2, varscan2
- SMCO3 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); catalogued as COSV99660571; called by muse, mutect2, varscan2
- SMYD5 | c.989A>T p.N330I | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99240143; called by muse, mutect2, varscan2
- SNPH | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.634); catalogued as COSV100377977; called by muse, mutect2, varscan2
- SOHLH2 | c.610_611del p.L204Sfs*18 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs776224525; called by pindel, varscan2
- SPANXN2 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 82/536 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs782723983, COSV100979808, COSV65128859; called by muse, varscan2
- SRRM2 | c.5777G>C p.R1926T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs1269616180, COSV100070287; called by muse, mutect2
- ST7L | c.827A>C p.H276P | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100573662; called by muse, mutect2, varscan2
- SYNE1 | c.3319G>A p.E1107K (on ENST00000367255 / NM_182961.4; = p.E1114K on NM_033071.3) | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV54938150; called by muse, mutect2, varscan2
- TBX19 | c.352A>T p.S118C | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100892333; called by muse, mutect2, varscan2
- TENM1 | c.3634G>C p.D1212H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949199, COSV64446915; called by muse, mutect2, varscan2
- TEX11 | c.927A>C p.K309N (on ENST00000344304; = p.K294N on NM_031276.3) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100721366; called by muse, mutect2, varscan2
- TKTL2 | c.618C>G p.C206W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99761143, COSV99761177; called by muse, mutect2, varscan2
- TNS4 | c.1736C>G p.S579C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV99563616; called by muse, mutect2, varscan2
- TPTE | c.1386A>G p.I462M (on ENST00000618007 / NM_199261.4; = p.I444M on NM_199259.4) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1455136362; called by muse, mutect2, varscan2
- TRAV25 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219742521; called by muse, mutect2
- TRHDE | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as COSV53855548; called by muse, mutect2, varscan2
- TTC17 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99234760; called by muse, mutect2, varscan2
- UBE3C | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61952548; called by muse, mutect2
- UBQLN2 | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100592629; called by muse, mutect2, varscan2
- UGT2B15 | c.1593G>C p.*531Yext*9 | Nonstop Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as rs1360895059, COSV100592228; called by muse, varscan2
- VTCN1 | c.781T>A p.C261S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100061431; called by muse, mutect2, varscan2
- ZIC4 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101267843; called by muse, mutect2, varscan2
- ZNF107 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.737); catalogued as COSV61326971; called by muse, mutect2, varscan2
- ZNF141 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV99549454; called by muse, mutect2, varscan2
- ZNF182 | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 11/130 reads (8%) | catalogued as COSV100526909; called by muse, mutect2
- ZNF239 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100021722; called by muse, mutect2
- ZNF318 | c.6676G>C p.D2226H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.748); catalogued as rs1360030172, COSV100545975; called by muse, mutect2, varscan2
- ZNF366 | c.2057A>G p.E686G | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100574112; called by muse, mutect2, varscan2
- ZNF423 | c.568G>A p.D190N (on ENST00000563137 / NM_001379286.1; = p.D182N on NM_015069.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99280131; called by muse, mutect2, varscan2
- ZNF804A | c.751A>G p.R251G | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100166598; called by muse, mutect2, varscan2
- IGLV9-49 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- PGS1 | c.163del p.A55Lfs*56 | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.999C>G p.I333M | Missense Mutation (SNP) | VAF 63/434 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TXNIP | c.251-3del | Splice Region (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- ZNF630 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCC12 | c.396G>C p.L132= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100252222; called by muse, mutect2, varscan2
- ADAMTS19 | c.2391C>A p.I797= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV50802384; called by muse, mutect2, varscan2
- ADGRG2 | c.450C>A p.V150= (on ENST00000379869 / NM_001079858.3; = p.V147= on NM_005756.4) | Silent (SNP) | VAF 29/203 reads (14%) | catalogued as COSV100491927; called by muse, mutect2, varscan2
- ANXA7 | c.1245G>A p.L415= (on ENST00000372919 / NM_001320880.2; = p.L393= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100873403; called by muse, mutect2, varscan2
- AOC2 | c.831T>C p.S277= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV99513517; called by muse, mutect2, varscan2
- ARAF | c.996T>C p.D332= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99282993; called by muse, mutect2, varscan2
- ATP10D | c.48C>T p.I16= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs761007607, COSV99905252; called by muse, mutect2, varscan2
- ATP2B3 | c.1372C>T p.L458= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs782414629, COSV99683215; called by muse, mutect2, varscan2
- BRWD3 | c.879T>C p.C293= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100955692; called by muse, mutect2, varscan2
- CADM1 | c.1107C>T p.I369= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV100522146, COSV59005510; called by muse, varscan2
- CMTM7 | c.291C>T p.F97= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100569848; called by muse, mutect2
- COPA | c.2245C>T p.L749= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV104385904, COSV99614750; called by muse, mutect2, varscan2
- DHRS2 | c.100C>T p.L34= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99158788; called by muse, mutect2, varscan2
- DNAH3 | c.7578C>T p.I2526= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1237815708, COSV54512892; called by muse, mutect2, varscan2
- EIF5 | c.990C>T p.I330= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as rs757721525, COSV99384674; called by muse, mutect2
- EPHA7 | c.1815C>A p.T605= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV100993321, COSV65193880; called by muse, mutect2, varscan2
- FAM47C | c.519C>T p.D173= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100792325; called by muse, mutect2, varscan2
- FUT9 | c.282A>C p.T94= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100133161; called by muse, mutect2, varscan2
- GARRE1 | c.1722C>T p.S574= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs745778540, COSV55096479; called by muse, mutect2, varscan2
- GRIA3 | c.2502T>C p.G834= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs1556337781, COSV99989145; ClinVar: likely benign; called by muse, mutect2, varscan2
- HCN1 | c.1773A>T p.L591= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as COSV100298818; called by muse, mutect2, varscan2
- HDAC8 | c.39G>T p.S13= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs1556166100, COSV101002347, COSV101002378; called by muse, mutect2, varscan2
- HPS1 | c.789G>A p.R263= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100282370; called by muse, mutect2, varscan2
- LRP2 | c.8772C>T p.I2924= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV99786759; called by muse, mutect2, varscan2
- LSAMP | c.444C>T p.N148= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs780626885, COSV61282793; called by muse, mutect2, varscan2
- MYCT1 | c.237G>T p.G79= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100924039; called by muse, mutect2
- MYH8 | c.4470C>G p.V1490= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101238262; called by muse, mutect2, varscan2
- NFE2L2 | c.444C>T p.P148= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs535776153, COSV101229321; called by muse, mutect2, varscan2
- OR4D9 | c.537C>T p.C179= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as rs145873782, COSV100259733; called by muse, mutect2, varscan2
- OR8D2 | c.681T>C p.G227= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV100658904; called by muse, mutect2, varscan2
- OR9Q1 | c.876G>A p.R292= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV59039006; called by muse, mutect2, varscan2
- PHKA1 | c.675A>G p.Q225= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100262535; called by muse, mutect2, varscan2
- PLS1 | c.1227A>T p.G409= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100537970; called by muse, mutect2, varscan2
- PNMA3 | c.1207C>A p.R403= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100937556, COSV100937632; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1068C>T p.V356= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs773003774, COSV99460891; called by muse, mutect2
- PRAMEF2 | c.678T>C p.C226= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as COSV99534864; called by muse, mutect2, varscan2
- PRDM9 | c.2181G>T p.R727= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as COSV99689859; called by muse, varscan2
- PTPRM | c.1287G>A p.V429= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs781152526, COSV100155307; called by muse, mutect2, varscan2
- RHCE | c.480C>T p.I160= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV99603764; called by muse, mutect2, varscan2
- RNASEL | c.501A>T p.G167= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100842549; called by muse, mutect2, varscan2
- RTL3 | c.1395C>A p.A465= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100329556, COSV58184367; called by mutect2, varscan2
- SHC3 | c.561C>T p.R187= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs940345621, COSV65440103; called by muse, mutect2, varscan2
- TAF1 | c.2883G>T p.P961= (on ENST00000373790 / NM_138923.4; = p.P982= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV99334647; called by muse, mutect2, varscan2
- TENM4 | c.6783G>T p.L2261= | Silent (SNP) | VAF 34/226 reads (15%) | catalogued as COSV99571653; called by muse, mutect2, varscan2
- TENT4A | c.1551G>A p.P517= | Silent (SNP) | VAF 22/428 reads (5%) | catalogued as rs755913044, COSV50097075; called by muse, mutect2
- TIE1 | c.3024G>A p.V1008= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100992000; called by muse, mutect2, varscan2
- TRIM29 | c.210C>T p.F70= | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as COSV59280384; called by muse, mutect2, varscan2
- TTN | c.57210C>A p.G19070= (on ENST00000591111; = p.G11646= on NM_003319.4) | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV100596659; called by muse, mutect2, varscan2
- TUBGCP2 | c.621G>A p.T207= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1168439140, COSV99427254; called by mutect2, varscan2
- YIPF2 | c.726G>T p.G242= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99449855; called by muse, mutect2, varscan2
- ZNF804A | c.1413T>C p.N471= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV100166600; called by muse, mutect2
- EI24P4 | n.864A>G | RNA (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2, varscan2
- MIR513B | n.81A>C | RNA (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- RPL27A | c.319-203C>G | Intron (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100029898; called by muse, mutect2, varscan2
- TUBB7P | n.211G>T | RNA (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
